Somatic mutation profile of tumor specimen C3L-02956-01 (aliquot CPT0161630031) from CPTAC case C3L-02956, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 84.1 years (30,711 days).
Specimen C3L-02956-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c519308-388b-48a8-8870-c5d724387fe8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02956-31 (Blood Derived Normal), aliquot CPT0162530002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0401e15-5d55-4239-b50f-f9549305abae

The open-access MAF lists 49 somatic variants for this specimen: 29 protein-altering or splice-affecting, 12 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 12, Intron 3, 3'UTR 2, RNA 2, Splice Region 1, Frame Shift Del 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 60/304 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CADPS2 | c.2738G>A p.R913Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs866025011, COSV100466546; called by muse, mutect2
- CDKN2A | c.47_50del p.L16Pfs*9 | Frame Shift Del (DEL) | VAF 24/222 reads (11%) | catalogued as rs587782206; called by pindel, varscan2
- HEPH | c.3418C>G p.R1140G (on ENST00000343002; = p.R873G on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57966393; called by muse, mutect2, varscan2
- ITGAX | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764269268; called by muse, mutect2
- LMTK2 | c.1101C>G p.D367E | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV51998808; called by muse, mutect2, varscan2
- MPP3 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 27/341 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200575347; called by muse, mutect2
- PCDH11X | c.2431G>T p.V811F | Missense Mutation (SNP) | VAF 30/399 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV53457151; called by muse, mutect2
- RYR2 | c.4754G>A p.R1585H | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1392451418, COSV63661428; called by muse, mutect2
- SLC44A4 | c.1768G>A p.V590I | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs770095927; called by muse, mutect2
- TGM6 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 17/259 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs757439955; called by muse, mutect2
- ZFHX4 | c.5237C>T p.T1746M | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); catalogued as rs753245273, COSV99259316; called by muse, mutect2, varscan2
- C4orf54 | c.3931A>G p.K1311E | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCNF | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2
- CHM | c.1489A>T p.M497L | Missense Mutation (SNP) | VAF 10/309 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2
- CNKSR2 | c.1205G>T p.R402I | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2
- FJX1 | c.1070A>G p.N357S | Missense Mutation (SNP) | VAF 106/565 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- FRY | c.7012C>G p.P2338A | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GLI4 | c.224-4del | Splice Region (DEL) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- MIEF2 | c.578A>T p.H193L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2
- PADI3 | c.1987G>A p.V663M | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.254); called by muse, mutect2
- PIGO | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RPS6KA3 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 14/215 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.034); called by muse, mutect2
- SLC25A46 | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- TAF3 | c.532A>G p.K178E | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2
- TP53 | c.616_645del p.L206_S215del | In Frame Del (DEL) | VAF 54/422 reads (13%) | called by mutect2, pindel
- TRIM71 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.99); PolyPhen benign (0.029); called by muse, mutect2
- ZNF267 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF536 | c.878T>C p.I293T | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHPF | c.1642C>T p.L548= | Silent (SNP) | VAF 15/168 reads (9%) | catalogued as COSV60535657; called by muse, mutect2
- DEAF1 | c.1674C>T p.S558= | Silent (SNP) | VAF 99/453 reads (22%) | catalogued as rs766292709; called by muse, mutect2, varscan2
- GLB1L2 | c.765C>T p.H255= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs139338435; called by muse, mutect2, varscan2
- HPR | c.60G>A p.L20= | Silent (SNP) | VAF 35/273 reads (13%) | catalogued as rs767678228; called by muse, mutect2, varscan2
- IGSF21 | c.1176C>T p.F392= | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as rs139607566; called by muse, mutect2
- IQSEC1 | c.2874G>A p.P958= | Silent (SNP) | VAF 13/128 reads (10%) | catalogued as rs150774031; called by muse, mutect2
- KIR2DS4 | c.483C>T p.N161= | Silent (SNP) | VAF 22/402 reads (5%) | catalogued as rs761946010; called by muse, mutect2
- NAP1L3 | c.288C>T p.F96= | Silent (SNP) | VAF 39/253 reads (15%) | catalogued as COSV100220657; called by muse, mutect2, varscan2
- NBAS | c.2406C>T p.C802= | Silent (SNP) | VAF 14/260 reads (5%) | catalogued as rs748466608, COSV99866303; called by muse, mutect2
- NR2F1 | c.792G>A p.A264= | Silent (SNP) | VAF 36/333 reads (11%) | called by muse, mutect2, varscan2
- RASGRF1 | c.288G>A p.T96= | Silent (SNP) | VAF 20/216 reads (9%) | catalogued as rs139580872; called by muse, mutect2
- TECTA | c.3723T>C p.C1241= | Silent (SNP) | VAF 22/335 reads (7%) | called by muse, mutect2
- CTCFL | c.1674+1023A>T | Intron (SNP) | VAF 25/204 reads (12%) | catalogued as rs1344354161; called by muse, mutect2
- LDLRAD2 | c.*1316C>T | 3'UTR (SNP) | VAF 15/266 reads (6%) | called by muse, mutect2
- MFSD5 | chr12:53251834 G>A | 5'Flank (SNP) | VAF 26/325 reads (8%) | called by muse, mutect2
- MYOZ3 | c.425-173A>G | Intron (SNP) | VAF 8/179 reads (4%) | called by muse, mutect2
- NOB1 | c.63+16T>C | Intron (SNP) | VAF 14/212 reads (7%) | called by muse, mutect2
- OR56B3P | n.390T>C | RNA (SNP) | VAF 12/245 reads (5%) | called by muse, mutect2
- OR56B3P | n.391C>A | RNA (SNP) | VAF 12/244 reads (5%) | called by muse, mutect2
- PCDHA13 | c.*264C>T | 3'UTR (SNP) | VAF 17/188 reads (9%) | catalogued as rs782495760; called by muse, mutect2
